Somatic mutation profile of tumor specimen BA2051D (aliquot aq-BA2051D) from BEATAML1.0 case 2464, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.9 years (22,227 days).
Specimen BA2051D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45969c64-32d7-4392-9a76-b172763ad161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2503D (Solid Tissue Normal), aliquot aq-BA2503D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c719388b-5210-49ac-b187-f3348d0c0790

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CTR9 | c.1977C>A p.H659Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV63728849; called by muse, varscan2
- APOB | c.4988G>T p.S1663I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- DPF3 | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KLF6 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- LRRC42 | c.1234C>A p.Q412K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.13); called by muse, varscan2
- PAN3 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TPBGL | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2
- VPS13D | c.11147G>C p.R3716P | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HOXA10 | c.822G>T p.P274= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- KIAA1109 | c.201C>A p.G67= | Silent (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- MDC1 | c.5595G>A p.K1865= | Silent (SNP) | VAF 27/67 reads (40%) | called by muse, mutect2, varscan2
- ATP1A1 | chr1:116405640 A>G | 3'Flank (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
